Somatic mutation profile of tumor specimen TCGA-02-0047-01A (aliquot TCGA-02-0047-01A-01D-1490-08) from TCGA case TCGA-02-0047, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,759 days).
Specimen TCGA-02-0047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c802335e-281f-4c11-8588-29dc04bf3527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-0047-10A (Blood Derived Normal), aliquot TCGA-02-0047-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bfc590f-8fd6-4a9c-88e0-081d7fafef44

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 11, Nonsense Mutation 2, Splice Region 2, Frame Shift Del 2, RNA 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2301A>T p.L767F | Missense Mutation (SNP) | VAF 61/148 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705638, COSV66706950; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 58/172 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.1594G>A p.G532S (on ENST00000302538 / NM_021962.5; = p.G495S on NM_001092.5) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs1256042037, COSV52142812; called by muse, mutect2, varscan2
- ADAMTS2 | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs370350117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS7 | c.2749A>C p.S917R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66306302, COSV66306544; called by muse, mutect2, varscan2
- ARSG | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV71592695; called by muse, mutect2, varscan2
- ASAH1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs758747892, COSV50501558; called by muse, mutect2, varscan2
- BCL11A | c.1566G>C p.Q522H (on ENST00000335712 / NM_001365609.1; = p.Q556H on NM_018014.4) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV59625880; called by muse, mutect2, varscan2
- BTBD3 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 159/399 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV54778334; called by muse, mutect2, varscan2
- CD101 | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV56716777; called by muse, mutect2, varscan2
- CELSR1 | c.4760G>A p.G1587D | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53085497; called by muse, mutect2, varscan2
- CLSTN3 | c.1488G>A p.E496= | Splice Region (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56934625; called by muse, mutect2, varscan2
- DDX6 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50587924, COSV50588493; called by muse, mutect2, varscan2
- DEFB110 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV67017940; called by muse, mutect2
- DES | c.1066T>A p.F356I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV64659985; called by muse, mutect2, varscan2
- DNAJC28 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV58721330; called by muse, mutect2, varscan2
- EPHA5 | c.645A>T p.Q215H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56635575; called by muse, mutect2
- FBXO8 | c.330G>T p.G110= | Splice Region (SNP) | VAF 32/150 reads (21%) | catalogued as COSV67031094; called by muse, mutect2, varscan2
- FGA | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57394007; called by muse, mutect2
- GAL3ST4 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 140/440 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs752625557, CM1213082, COSV57585531; called by muse, mutect2, varscan2
- GFM2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs139234343; called by muse, mutect2, varscan2
- GPR132 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV61677695; called by muse, mutect2, varscan2
- HMG20B | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53571444; called by muse, mutect2, varscan2
- IGHV3-33 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.956); catalogued as rs577673308; called by muse, mutect2, varscan2
- IL1B | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | catalogued as rs953191369, COSV54521247; called by muse, mutect2
- LAMA2 | c.137T>A p.L46H | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70341945; called by muse, mutect2, varscan2
- LRP6 | c.4567C>T p.R1523W | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs761430379, COSV53784555; called by muse, mutect2
- MYO3A | c.2978T>A p.L993H | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV56323057; called by muse, mutect2, varscan2
- OR52I2 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100442968, COSV57044517; called by muse, mutect2
- OR5M3 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as rs1406730292, COSV56566078; called by muse, mutect2, varscan2
- PABPC3 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55798385; called by muse, mutect2, varscan2
- PCDHGA8 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.223); catalogued as COSV53914152; called by muse, mutect2, varscan2
- PLEKHG1 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV62045768; called by muse, mutect2, varscan2
- PLG | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.277); catalogued as rs1035024633, COSV57513647; called by muse, mutect2, varscan2
- RPRD1B | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV65032439; called by muse, mutect2, varscan2
- RYR3 | c.8412G>A p.M2804I (on ENST00000389232; = p.M2805I on NM_001036.6) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV66781381; called by muse, mutect2, varscan2
- SCYL1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399523797, COSV54211023; called by muse, mutect2, varscan2
- SLC35G3 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs553697473, COSV52010525, COSV52012034; called by muse, mutect2, varscan2
- SLC9A4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs768860169, COSV54829958; called by muse, mutect2, varscan2
- SOX10 | c.1401A>C p.*467Yext*86 | Nonstop Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as CM101963, COSV62806252; called by muse, varscan2
- SPTBN1 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs772259760, COSV61686507; called by muse, mutect2, varscan2
- TEAD1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV57562393, COSV57570254; called by muse, mutect2
- TPTE2 | c.472T>G p.Y158D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV55017518; called by muse, mutect2, varscan2
- TREML2 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV72439045; called by muse, mutect2, varscan2
- TUBA4A | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV50277819; called by muse, mutect2
- USP9X | c.5620C>T p.Q1874* | Nonsense Mutation (SNP) | VAF 48/74 reads (65%) | catalogued as COSV61067020; called by muse, mutect2, varscan2
- VPS13D | c.10043C>T p.P3348L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50626265; called by muse, mutect2, varscan2
- WWC2 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV67856591, COSV67862432; called by muse, mutect2, varscan2
- ZNF385D | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55749022; called by muse, mutect2, varscan2
- AC090517.4 | c.315del p.V106Lfs*12 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- IGHV3-73 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JUP | c.667T>G p.F223V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2
- RIMKLB | c.926_943del p.S309_R315delinsC | In Frame Del (DEL) | VAF 49/168 reads (29%) | called by mutect2, pindel, varscan2
- SPACA3 | c.252del p.S85Vfs*86 | Frame Shift Del (DEL) | VAF 49/142 reads (35%) | called by mutect2, pindel, varscan2
- AC242842.3 | c.630T>G p.T210= | Silent (SNP) | VAF 24/57 reads (42%) | called by mutect2, varscan2
- BUB1B | c.3135G>A p.G1045= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as COSV55010596; called by muse, mutect2, varscan2
- DNAH17 | c.7803C>T p.T2601= | Silent (SNP) | VAF 69/295 reads (23%) | catalogued as COSV101103946; called by muse, mutect2, varscan2
- DNAJC5B | c.63C>T p.Y21= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs764193345, COSV52535529; called by muse, mutect2, varscan2
- FAM83B | c.471T>C p.F157= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV60920183; called by muse, mutect2
- GFM2 | c.762A>G p.K254= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV57190033; called by muse, mutect2, varscan2
- GSDMA | c.253C>T p.L85= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV56975366; called by muse, mutect2, varscan2
- NAV1 | c.1563C>T p.I521= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV55215093; called by muse, mutect2
- PCNX2 | c.597G>A p.A199= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as rs200747953; called by muse, mutect2, varscan2
- PLXNB2 | c.3807G>A p.E1269= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs1324010303, COSV63780511; called by muse, mutect2, varscan2
- PTPRC | c.3213C>T p.I1071= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV61408083; called by muse, mutect2, varscan2
- AL163540.1 | n.49T>C | RNA (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
